Surgical pathology report (de-identified scan), TCGA case TCGA-66-2790, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2790-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lung

Clinical diagnosis and question

Squamous cell carcinoma of left upper lobe (according to histology, [REDACTED])

REPORT ON FINDINGS**Macroscopy**

- 1.) Left lung: inflated, fixed lung measuring 18.5 x 14.5 cm at the base, up to 23 cm high, central bronchus resection plane located 3 cm proximal to the division into the lobe bronchi. Main bronchus largely skeletonized. At the hilus two nodes, 1.5 cm and 2.2 cm in size. Visceral pleura, especially in the region of the upper lobe, predominantly patch blackish pigmentation, in the dorsal region over S6 and S10 an area of whitish thickening measuring about 11 x 4 cm, with an unclear demarcation. Centrally in the upper lobe, a firm tumor, about 4 cm in size, obstructing or markedly constricting the upper lobe bronchus and its segmental bronchi, distance of tumor from central bronchus resection line 3 cm. In the tumor margin area several partly tumor-infiltrated nodes. Distance of tumor from paracentral visceral pleura focally less than 0.1 cm. Bronchi peripheral to tumor slightly dilated and filled with mucus. Parenchyma of upper lobe shows small patches of slightly blackish pigmentation, that of the lower lobe is inconspicuous.
- 2.) Parietal pleura left: thick-skinned, partly plate-like bone-hard specimen measuring 3 x 2.3 cm and up to 1 cm thick.
- 3.) Hilar LN (station 10) left: 2.5 cm specimen with four nodes of max. 1.5 cm and one 0.5 cm node.
- 4.) Pulmonary ligament LN (station 9) left: 1.2 cm node with surrounding tissue.
- 5.) Low paratracheal LN (station 4) left: 1 cm node.
- 6.) Subcarinal LN (station 7): 1.7 cm node part.
- 7.) Paraaortic LN (station 6): four nodes between 0.6 cm and 1.5 cm.
- 8.) Subaortic LN (aortopulmonary window) (station 5): two nodes, 0.5 cm and 0.9 cm.
- 9.) Hilar LN (station 10) right: 1.5 cm node part.

Examined:

- 1.) a: Tumor with upper and lower lobe bronchus (lower lobe bronchus marked blue). b: two sections of tumor with pleura. c: one section with dilated mucus-filled bronchi. d: one section each from S6 (smaller specimen) and S10 (larger specimen) dorsal. e: infiltrated nodes in the tumor margin area (1 section each). f: nodes in the tumor margin area (lamellated). g+h: bronchus and vessel resection margins as well as smaller hilar node. i. larger hilar node (lamellated).
- 2.) 2 sections.
- 3.) - 9.) All material
- 17 blocks, partly Elastica-van Gieson, PAS, diastase-PAS and decalcification.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Central bronchopulmonary, histologically poorly differentiated, nonkeratinizing squamous cell carcinoma of the left upper lobe of the lung.

TNM classification according to this picture pT2 pN1 pMX VI R0, stage IIB. C 34.1, M 8070/3.

Secondary diagnosis/diagnoses:

Bronchiectases peripheral to the tumor in the upper lobe. Respiratory bronchiolitis. Slight centroacinar pulmonary emphysema. Marked fibrous enlargement and slight chronic inflammation of the visceral pleura over S6 and 10 (sample 1:)). Partially calcified, hypocellular fibrotic area of parietal pleura (sample 2:)). Lymph nodes with reactive lesions and anthracotic pigment deposits (samples 3.) to 9.)).

Remark/addendum:

The carcinoma shows central endobronchial growth with a papillary component. It has produced some central parabronchial and hilar lymph node metastases in the main preparation. The resection margin of the bronchus and vessels, the visceral pleura, the lower lobe and the lymph nodes of samples 3.) to 9.) are tumor-free.

Source: NCI Genomic Data Commons file 4bde8df8-d9a2-4f2f-b6dd-7bb0be982041 (TCGA-66-2790.7E17DC53-B237-46DB-B6D6-86B7EEB51BAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).